Somatic mutation profile of tumor specimen 8d78194e-fbef-4819-a7b5-b73ae9 (aliquot 8d78194e-fbef-4819-a7b5-b73ae9_D6) from CPTAC case 02OV042, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 8d78194e-fbef-4819-a7b5-b73ae9: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf9c9afa-d3d9-4824-9714-d8ff6f9afc81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 120aa31e-f256-4f22-baf4-873bf8 (Blood Derived Normal), aliquot 120aa31e-f256-4f22-baf4-873bf8_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f395fed-ec81-493f-8f75-d6b2013cf72b

The open-access MAF lists 247 somatic variants for this specimen: 184 protein-altering or splice-affecting, 36 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 36, Intron 15, Nonsense Mutation 13, Frame Shift Del 10, In Frame Del 7, Splice Region 5, RNA 4, Splice Site 4, 5'Flank 3, 3'UTR 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAP3 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs771507543; called by muse, mutect2, varscan2
- ACSL6 | c.724G>C p.G242R (on ENST00000379240; = p.G267R on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV99734902; called by muse, mutect2, varscan2
- AGAP3 | c.1001G>A p.R334Q (on ENST00000622464; = p.R370Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 169/281 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs764106397, COSV100103966; called by muse, mutect2, varscan2
- AK3 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV63347289; called by muse, mutect2, varscan2
- ANKRD50 | c.977T>C p.I326T | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775400702, COSV72386362; called by muse, mutect2, varscan2
- ARID1A | c.1897C>T p.Q633* | Nonsense Mutation (SNP) | VAF 51/165 reads (31%) | catalogued as COSV61375026; called by muse, mutect2, varscan2
- C11orf80 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as rs757604266; called by muse, mutect2, varscan2
- C1orf105 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 50/314 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs768793316; called by muse, mutect2, varscan2
- CD160 | c.196G>C p.G66R | Missense Mutation (SNP) | VAF 110/507 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV52523341; called by muse, mutect2, varscan2
- CDK14 | c.864C>G p.Y288* (on ENST00000380050 / NM_001287135.2; = p.Y270* on NM_012395.3) | Nonsense Mutation (SNP) | VAF 49/283 reads (17%) | catalogued as rs551786255; called by muse, mutect2, varscan2
- CPEB2 | c.1684T>A p.W562R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs768036036; called by muse, mutect2, varscan2
- CYTIP | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 106/450 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV51635200; called by muse, mutect2, varscan2
- DDX5 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV56748565; called by muse, mutect2, varscan2
- DNAH6 | c.3473C>A p.P1158Q | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV52864280; called by muse, mutect2
- FAM71F1 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 203/419 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59373377; called by muse, mutect2, varscan2
- FEM1A | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 122/597 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.07); catalogued as rs1280670500; called by muse, mutect2, varscan2
- FKBP1C | c.299T>C p.F100S | Missense Mutation (SNP) | VAF 105/275 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs548161473; called by muse, mutect2, varscan2
- GLRA2 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs909312779, COSV54341039, COSV99028762; called by muse, mutect2, varscan2
- HMGXB3 | c.1667G>A p.R556Q (on ENST00000613459; = p.R310Q on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs1376780446; called by muse, mutect2, varscan2
- HSPG2 | c.9842C>G p.T3281S | Missense Mutation (SNP) | VAF 130/754 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.033); catalogued as rs1468268553; called by muse, varscan2
- IGHV1OR21-1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 86/745 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1482563087; called by muse, mutect2, varscan2
- IL27RA | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as rs765688324; called by muse, mutect2, varscan2
- KHDRBS3 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 39/117 reads (33%) | catalogued as rs1173128434, COSV63424392; called by muse, mutect2, varscan2
- KIF17 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 247/635 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs547253363; called by muse, mutect2, varscan2
- LARS1 | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99198647; called by muse, mutect2, varscan2
- LETM1 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs777813839; called by muse, mutect2, varscan2
- LGMN | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs751929913; called by muse, mutect2, varscan2
- LRFN2 | c.1423G>T p.A475S | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0.028); catalogued as rs776145223; called by muse, mutect2, varscan2
- ME1 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs756328212; called by muse, mutect2, varscan2
- METTL17 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 69/394 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs199822122, COSV53868670; called by muse, mutect2, varscan2
- NTNG2 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 207/503 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765705117, COSV100647173; called by muse, mutect2, varscan2
- OR2B2 | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 274/421 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100308030, COSV100308096; called by muse, mutect2, varscan2
- OR2L13 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 86/543 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs553614392, COSV63560530; called by muse, mutect2, varscan2
- OR4Q3 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 103/468 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV59178862; called by muse, mutect2, varscan2
- PDE4A | c.1823G>A p.R608H (on ENST00000380702 / NM_001111307.2; = p.R369H on NM_006202.3) | Missense Mutation (SNP) | VAF 99/408 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53354045; called by muse, mutect2, varscan2
- PPRC1 | c.3142C>T p.P1048S | Missense Mutation (SNP) | VAF 101/297 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs140572262; called by muse, mutect2, varscan2
- PTPRD | c.4448C>T p.T1483M | Missense Mutation (SNP) | VAF 65/382 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs753080783; called by muse, mutect2, varscan2
- RBM41 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752239874; called by muse, mutect2, varscan2
- RFX4 | c.1588C>A p.P530T (on ENST00000392842 / NM_213594.3; = p.P436T on NM_032491.6) | Missense Mutation (SNP) | VAF 90/157 reads (57%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.108); catalogued as COSV99986315; called by muse, mutect2, varscan2
- SCN8A | c.3490+8G>A | Splice Region (SNP) | VAF 27/139 reads (19%) | catalogued as rs1469519963; called by muse, mutect2, varscan2
- SHOX | c.252A>T p.E84D | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as CD134669; called by muse, mutect2, varscan2
- SIK3 | c.3030C>G p.I1010M (on ENST00000445177 / NM_001366686.2; = p.I968M on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.053); catalogued as COSV52616183; called by muse, mutect2, varscan2
- SLC10A3 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 316/730 reads (43%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs782431405, COSV54836362; called by mutect2, varscan2
- SLC1A2 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145275821; called by muse, mutect2, varscan2
- SLC27A1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 128/436 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs1402481308; called by muse, varscan2
- SLC39A6 | c.1643T>G p.L548R | Missense Mutation (SNP) | VAF 182/243 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1353212468; called by muse, mutect2, varscan2
- SNAP91 | c.340G>T p.G114* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV52129627; called by muse, mutect2, varscan2
- SPTBN2 | c.4655G>A p.R1552H | Missense Mutation (SNP) | VAF 169/686 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs182094691; called by muse, mutect2, varscan2
- SV2B | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 31/135 reads (23%) | catalogued as rs202215568; called by muse, mutect2, varscan2
- TMEM86B | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs755484206; called by muse, mutect2, varscan2
- TRPS1 | c.1562C>T p.T521M (on ENST00000220888 / NM_001330599.2; = p.T534M on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 517/633 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs371058224; called by muse, mutect2, varscan2
- TTN | c.99923G>A p.R33308H (on ENST00000591111; = p.R25884H on NM_003319.4) | Missense Mutation (SNP) | VAF 143/494 reads (29%) | PolyPhen probably damaging (0.998); catalogued as rs375818056; called by muse, mutect2, varscan2
- TUBGCP3 | c.1841G>A p.S614N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs756042724; called by muse, mutect2, varscan2
- TUBGCP6 | c.2185G>A p.D729N | Missense Mutation (SNP) | VAF 82/136 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1157310018; called by muse, mutect2, varscan2
- VPS13C | c.5503C>G p.P1835A (on ENST00000644861 / NM_020821.3; = p.P1792A on NM_017684.5) | Missense Mutation (SNP) | VAF 117/131 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51306904; called by muse, mutect2, varscan2
- WRAP73 | c.880_895del p.P294Afs*22 | Frame Shift Del (DEL) | VAF 83/194 reads (43%) | catalogued as rs1232275618; called by mutect2, pindel, varscan2
- ZSCAN31 | c.872G>C p.G291A | Missense Mutation (SNP) | VAF 398/745 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs150046166; called by muse, mutect2, varscan2
- ABHD12 | c.474G>T p.M158I | Missense Mutation (SNP) | VAF 101/621 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACSL4 | c.1412C>T p.S471L (on ENST00000340800 / NM_022977.2; = p.S430L on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/133 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ACSS2 | c.976G>C p.V326L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by mutect2, varscan2
- ADAMTS3 | c.1865_1870del p.S622_H623del | In Frame Del (DEL) | VAF 55/172 reads (32%) | called by mutect2, pindel, varscan2
- ADCY4 | c.1091A>T p.N364I | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP6 | c.3454_3480del p.E1152_H1160del | In Frame Del (DEL) | VAF 43/278 reads (15%) | called by mutect2, pindel, varscan2
- ANK2 | c.8102C>G p.S2701C | Missense Mutation (SNP) | VAF 120/468 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP3D1 | c.969del p.L324Cfs*8 | Frame Shift Del (DEL) | VAF 44/115 reads (38%) | called by mutect2, pindel, varscan2
- BCL2L14 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 28/640 reads (4%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2
- BHLHE41 | c.285C>A p.H95Q | Missense Mutation (SNP) | VAF 340/443 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRSK1 | c.2254G>T p.D752Y | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- BTBD8 | c.2861C>A p.S954Y (on ENST00000636805 / NM_001376131.1; = p.S441Y on NM_015237.4) | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- C1QBP | c.827A>G p.K276R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- C1QTNF5 | c.679T>A p.F227I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CACNG5 | c.332T>G p.M111R | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- CAD | c.2187del p.F729Lfs*10 | Frame Shift Del (DEL) | VAF 35/172 reads (20%) | called by mutect2, pindel, varscan2
- CAD | c.5458C>G p.L1820V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALU | c.668A>T p.N223I | Missense Mutation (SNP) | VAF 94/533 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- CCDC121 | c.678G>T p.R226S | Missense Mutation (SNP) | VAF 149/211 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- CEP350 | c.865A>T p.I289F | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHPF | c.2049C>G p.D683E | Missense Mutation (SNP) | VAF 94/254 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL11A2 | c.3790G>A p.G1264R (on ENST00000341947 / NM_080680.3; = p.G1157R on NM_080679.2) | Missense Mutation (SNP) | VAF 218/650 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPEB2 | c.1685G>T p.W562L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- CROCC | c.3756G>C p.E1252D | Missense Mutation (SNP) | VAF 149/424 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CSGALNACT1 | c.1399A>T p.T467S | Missense Mutation (SNP) | VAF 116/292 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DAZL | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated, low confidence (0.22); called by muse, mutect2, varscan2
- DDR2 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 16/256 reads (6%) | called by muse, mutect2
- DSPP | c.813A>C p.K271N | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DYDC2 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 85/158 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); called by muse, varscan2
- ELF3 | c.478+3G>T | Splice Region (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- EML5 | c.464_480del p.D155Vfs*5 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- ERVV-1 | c.1304A>T p.K435I | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- FBP2 | c.786C>G p.I262M | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FN1 | c.3137C>A p.P1046H | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GABPB1 | c.1052A>T p.Q351L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GARRE1 | c.2759C>A p.A920D | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GIT1 | c.1098C>A p.N366K | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- GPX3 | c.126G>C p.E42D | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GTF3A | c.325C>G p.Q109E | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- GZF1 | c.1155G>T p.K385N | Missense Mutation (SNP) | VAF 77/340 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- H2AC16 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 36/512 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- HCFC1 | c.977G>A p.C326Y | Missense Mutation (SNP) | VAF 137/264 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HNRNPUL2 | c.812C>G p.S271* | Nonsense Mutation (SNP) | VAF 30/190 reads (16%) | called by muse, varscan2
- IFIT1B | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- INPP5F | c.398C>G p.T133S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- INSC | c.1501C>G p.P501A | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- INTS6 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- IQSEC2 | c.4013G>T p.R1338L | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ITGAL | c.2366G>A p.R789K | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.257); called by muse, mutect2
- KDF1 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 131/758 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KDR | c.2440_2467del p.D814Mfs*12 | Frame Shift Del (DEL) | VAF 96/528 reads (18%) | called by mutect2, pindel, varscan2
- KIF17 | c.833T>A p.V278E | Missense Mutation (SNP) | VAF 99/284 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KMT2A | c.5070_5087del p.D1690_T1695del | In Frame Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel
- KNG1 | c.178A>T p.T60S | Missense Mutation (SNP) | VAF 237/411 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- KREMEN1 | c.113C>A p.A38E (on ENST00000407188; = p.A40E on NM_032045.5) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by mutect2, varscan2
- LAMA1 | c.744A>T p.E248D | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAMC1 | c.838_840del p.F280del | In Frame Del (DEL) | VAF 30/180 reads (17%) | called by mutect2, pindel, varscan2
- LETM1 | c.1479G>A p.K493= | Splice Region (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- LPIN3 | c.1660C>A p.Q554K | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAP1B | c.4355G>T p.S1452I | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAPK8 | c.616G>T p.V206L (on ENST00000374189 / NM_139049.4; = p.V206F on NM_139046.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- MDC1 | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.203); called by muse, mutect2
- MED13L | c.766_779del p.E256Ifs*2 | Frame Shift Del (DEL) | VAF 85/524 reads (16%) | called by mutect2, pindel, varscan2
- MED14 | c.1941G>A p.M647I | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- MINK1 | c.3556G>T p.G1186C | Missense Mutation (SNP) | VAF 75/88 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYH4 | c.1123_1147+16del p.X375_splice | Splice Site (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- MYLK2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 78/376 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NELL1 | c.1293C>A p.Y431* | Nonsense Mutation (SNP) | VAF 35/172 reads (20%) | called by muse, mutect2, varscan2
- NFIA | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NINL | c.564G>T p.K188N | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- NINL | c.562A>T p.K188* | Nonsense Mutation (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- NPBWR2 | c.245_285del p.V82Afs*226 | Frame Shift Del (DEL) | VAF 102/706 reads (14%) | called by mutect2, pindel
- NRP1 | c.1382A>T p.N461I | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- NTAQ1 | c.357T>A p.D119E | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- OBSCN | c.21937T>G p.Y7313D | Missense Mutation (SNP) | VAF 178/891 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- OFD1 | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR5T2 | c.199T>C p.F67L | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR7G1 | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- P3H3 | c.1139T>A p.I380N | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PACS1 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- PAPPA | c.2111+1G>A p.X704_splice | Splice Site (SNP) | VAF 24/111 reads (22%) | called by muse, varscan2
- PCDHGB1 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- PCSK5 | c.5526T>A p.D1842E | Missense Mutation (SNP) | VAF 111/174 reads (64%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE4A | c.865A>G p.T289A (on ENST00000380702 / NM_001111307.2; = p.T50A on NM_006202.3) | Missense Mutation (SNP) | VAF 98/201 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PFDN6 | c.229G>C p.G77R | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PLS3 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- PRSS16 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- PTCD2 | c.905C>A p.S302* | Nonsense Mutation (SNP) | VAF 23/105 reads (22%) | called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.701T>G p.F234C (on ENST00000421990 / NM_001136042.2; = p.F216C on NM_025267.3) | Missense Mutation (SNP) | VAF 91/102 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PWWP3A | c.1153A>G p.M385V (on ENST00000627377; = p.M384V on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/90 reads (72%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PWWP3B | c.1561G>T p.D521Y | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PZP | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASSF2 | c.384G>T p.R128S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0.01); called by mutect2, varscan2
- RNFT2 | c.1108G>C p.V370L | Missense Mutation (SNP) | VAF 222/338 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SEMA3D | c.2327_2334del p.A776Vfs*6 | Frame Shift Del (DEL) | VAF 60/147 reads (41%) | called by mutect2, pindel, varscan2
- SEMG2 | c.802C>A p.H268N | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.02); called by muse, mutect2
- SEPTIN4 | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.716); called by muse, mutect2
- SERPINA9 | c.479T>A p.V160D | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- SETD1B | c.3910+2T>A p.X1304_splice | Splice Site (SNP) | VAF 44/86 reads (51%) | called by muse, mutect2, varscan2
- SLC1A2 | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A7 | c.1570C>A p.L524I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX8 | c.984G>A p.K328= | Splice Region (SNP) | VAF 44/72 reads (61%) | called by muse, mutect2, varscan2
- SPNS1 | c.1441A>T p.T481S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- SPPL2B | c.620_631del p.R207_G210del | In Frame Del (DEL) | VAF 122/169 reads (72%) | called by mutect2, pindel, varscan2
- SRPX | c.954A>C p.A318= | Splice Region (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- SS18L1 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 72/532 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- SSX2IP | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 36/147 reads (24%) | called by muse, mutect2, varscan2
- SYDE1 | c.2192_2194del p.I731del | In Frame Del (DEL) | VAF 25/95 reads (26%) | called by mutect2, pindel, varscan2
- TCAF1 | c.2444T>A p.L815Q | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- TET1 | c.3995A>C p.Q1332P | Missense Mutation (SNP) | VAF 80/394 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TEX14 | c.193T>G p.L65V | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TFPI2 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TLCD1 | c.307_352del p.V103Tfs*23 | Frame Shift Del (DEL) | VAF 22/148 reads (15%) | called by mutect2, pindel
- TMEM176B | c.389T>A p.L130Q | Missense Mutation (SNP) | VAF 90/558 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM183A | c.458T>A p.F153Y | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM266 | c.39-21_44del p.X13_splice | Splice Site (DEL) | VAF 54/219 reads (25%) | called by mutect2, pindel, varscan2
- TTN | c.15214T>A p.S5072T (on ENST00000591111; = p.S4145T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/147 reads (63%) | PolyPhen benign (0.12); called by muse, mutect2, varscan2
- UBLCP1 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VCAN | c.5256A>T p.L1752F | Missense Mutation (SNP) | VAF 174/579 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- VN1R4 | c.68T>C p.F23S | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- VPS13B | c.6297A>C p.K2099N | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- VPS13C | c.2790_2795del p.E930_E931del (on ENST00000644861 / NM_020821.3; = p.E887_E888del on NM_017684.5) | In Frame Del (DEL) | VAF 34/97 reads (35%) | called by mutect2, pindel, varscan2
- ZBTB7A | c.1233G>C p.E411D | Missense Mutation (SNP) | VAF 149/323 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ZNF528 | c.974_980del p.Y325Lfs*14 | Frame Shift Del (DEL) | VAF 101/185 reads (55%) | called by mutect2, pindel, varscan2
- ZNF620 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 114/199 reads (57%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ZRANB3 | c.2052T>A p.C684* | Nonsense Mutation (SNP) | VAF 24/248 reads (10%) | called by muse, mutect2
- ZRANB3 | c.2051G>T p.C684F | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.071); called by muse, mutect2
- ADSS1 | c.1194G>A p.K398= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV58273100; called by muse, mutect2, varscan2
- AMY2A | c.576T>C p.S192= | Silent (SNP) | VAF 200/787 reads (25%) | catalogued as rs1414158177; called by muse, mutect2, varscan2
- ARHGAP15 | c.1023C>T p.D341= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as rs138120208; called by muse, varscan2
- ASIC3 | c.420C>A p.P140= | Silent (SNP) | VAF 209/398 reads (53%) | called by muse, mutect2, varscan2
- BUD23 | c.72G>C p.R24= | Silent (SNP) | VAF 85/357 reads (24%) | called by muse, mutect2, varscan2
- CCDC185 | c.1131G>T p.R377= | Silent (SNP) | VAF 43/240 reads (18%) | called by muse, mutect2, varscan2
- CFAP65 | c.993C>T p.S331= | Silent (SNP) | VAF 74/193 reads (38%) | catalogued as rs778634556; called by muse, mutect2, varscan2
- CRHR1 | c.639C>T p.N213= (on ENST00000398285 / NM_001145146.2; = p.N184= on NM_004382.5) | Silent (SNP) | VAF 89/292 reads (30%) | catalogued as rs774890290, COSV53277779; called by muse, mutect2, varscan2
- DEFB118 | c.309T>G p.V103= | Silent (SNP) | VAF 89/401 reads (22%) | catalogued as COSV53620271; called by muse, mutect2, varscan2
- DOCK9 | c.2808C>G p.T936= (on ENST00000376460 / NM_001366676.2; = p.T937= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/128 reads (30%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.2685G>A p.V895= | Silent (SNP) | VAF 154/367 reads (42%) | called by muse, mutect2, varscan2
- EIF2B5 | c.147C>G p.A49= | Silent (SNP) | VAF 114/215 reads (53%) | called by muse, mutect2, varscan2
- GSN | c.600C>T p.A200= | Silent (SNP) | VAF 122/527 reads (23%) | catalogued as rs1421632752; called by muse, mutect2, varscan2
- HECTD1 | c.4587C>T p.S1529= | Silent (SNP) | VAF 104/280 reads (37%) | called by muse, mutect2, varscan2
- INTS6L | c.1575C>G p.T525= | Silent (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- ITGAE | c.3165G>T p.V1055= | Silent (SNP) | VAF 77/149 reads (52%) | called by muse, mutect2, varscan2
- JSRP1 | c.306G>T p.P102= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- KIR2DL1 | c.366C>T p.I122= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as COSV99383446; called by muse, mutect2, varscan2
- KLHDC7A | c.1515C>A p.S505= | Silent (SNP) | VAF 78/458 reads (17%) | called by muse, varscan2
- LARP1 | c.21G>A p.L7= | Silent (SNP) | VAF 83/352 reads (24%) | called by muse, mutect2, varscan2
- LBR | c.1698C>T p.H566= | Silent (SNP) | VAF 44/313 reads (14%) | catalogued as rs749951689; called by muse, mutect2, varscan2
- LRP2 | c.2028C>A p.L676= | Silent (SNP) | VAF 354/657 reads (54%) | catalogued as COSV55552440; called by muse, mutect2, varscan2
- MLIP | c.450C>A p.P150= | Silent (SNP) | VAF 57/259 reads (22%) | catalogued as COSV51437080; called by muse, mutect2, varscan2
- MROH2B | c.3078C>T p.A1026= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as rs768202807, COSV68183154; called by muse, mutect2, varscan2
- MRPL41 | c.324C>G p.T108= | Silent (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- MTUS2 | c.369C>A p.T123= | Silent (SNP) | VAF 83/344 reads (24%) | called by muse, mutect2, varscan2
- MYT1L | c.2049C>A p.P683= | Silent (SNP) | VAF 76/378 reads (20%) | called by muse, mutect2, varscan2
- NPFFR1 | c.582C>T p.R194= | Silent (SNP) | VAF 276/664 reads (42%) | catalogued as rs1040385303; called by muse, mutect2
- PADI1 | c.288C>T p.Y96= | Silent (SNP) | VAF 196/362 reads (54%) | called by muse, mutect2, varscan2
- RELN | c.9231T>G p.P3077= | Silent (SNP) | VAF 176/561 reads (31%) | called by muse, mutect2, varscan2
- SLC12A2 | c.1704C>T p.C568= | Silent (SNP) | VAF 28/175 reads (16%) | called by muse, mutect2, varscan2
- SLC27A1 | c.267G>A p.Q89= | Silent (SNP) | VAF 126/430 reads (29%) | catalogued as rs1406088084; called by muse, varscan2
- SLC34A2 | c.981C>G p.L327= | Silent (SNP) | VAF 172/665 reads (26%) | catalogued as rs937323145; called by muse, mutect2, varscan2
- SLC9C2 | c.2625C>T p.L875= | Silent (SNP) | VAF 53/99 reads (54%) | catalogued as rs755694698, COSV100876551, COSV62948032; called by muse, mutect2, varscan2
- ZNF215 | c.219T>C p.C73= | Silent (SNP) | VAF 46/140 reads (33%) | called by muse, mutect2, varscan2
- ZNF850 | c.2940T>A p.P980= | Silent (SNP) | VAF 46/258 reads (18%) | called by muse, mutect2, varscan2
- AP000842.1 | n.428T>C | RNA (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- ASB10 | chr7:151187567 A>G | 5'Flank (SNP) | VAF 48/375 reads (13%) | called by muse, mutect2, varscan2
- ATP6V0A1 | c.2421-611T>A | Intron (SNP) | VAF 60/279 reads (22%) | called by muse, mutect2, varscan2
- C20orf204 | c.280-22C>T | Intron (SNP) | VAF 71/180 reads (39%) | catalogued as rs1163897551; called by muse, mutect2, varscan2
- C4orf50 | c.-566_-552del | 5'UTR (DEL) | VAF 139/357 reads (39%) | called by mutect2, pindel, varscan2
- CAPN3 | c.1800+14T>C | Intron (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- DDX4 | c.69+3146C>T | Intron (SNP) | VAF 34/135 reads (25%) | called by muse, mutect2, varscan2
- DEPDC5 | c.3264-12G>T | Intron (SNP) | VAF 16/54 reads (30%) | called by muse, varscan2
- DPF1 | c.677-25C>G | Intron (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- ELAVL2 | c.-12-2813G>A | Intron (SNP) | VAF 13/157 reads (8%) | called by muse, mutect2
- ETV4 | c.60+58C>A | Intron (SNP) | VAF 48/85 reads (56%) | called by muse, mutect2, varscan2
- NDUFAF1 | c.-339G>C | 5'UTR (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2
- PEX19 | c.*1935A>G | 3'UTR (SNP) | VAF 257/592 reads (43%) | called by muse, mutect2, varscan2
- PRRT2 | chr16:29811843 C>T | 5'Flank (SNP) | VAF 46/175 reads (26%) | catalogued as rs543996612; called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895788 A>G | 5'Flank (SNP) | VAF 56/243 reads (23%) | called by muse, mutect2, varscan2
- SHMT1 | c.243-25T>G | Intron (SNP) | VAF 177/274 reads (65%) | called by muse, mutect2, varscan2
- SHOC2 | c.-235+17321T>G | Intron (SNP) | VAF 175/651 reads (27%) | called by muse, mutect2, varscan2
- SLC22A17 | n.1262C>T | RNA (SNP) | VAF 52/307 reads (17%) | called by muse, mutect2, varscan2
- SLC7A7 | c.-180-106A>T | Intron (SNP) | VAF 134/643 reads (21%) | catalogued as rs546751484; called by muse, mutect2, varscan2
- SMTN | c.1632+1674A>T | Intron (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2
- SPATA31C2 | n.2141C>T | RNA (SNP) | VAF 132/503 reads (26%) | called by muse, mutect2, varscan2
- SSPOP | n.9038T>A | RNA (SNP) | VAF 66/548 reads (12%) | catalogued as COSV100947429; called by mutect2, varscan2
- TAZ | c.285-23T>A | Intron (SNP) | VAF 73/586 reads (12%) | called by muse, mutect2, varscan2
- TNFRSF18 | c.*72T>C | 3'UTR (SNP) | VAF 43/283 reads (15%) | catalogued as rs758155125; called by muse, mutect2, varscan2
- UBE4A | chr11:118401598 C>T | 3'Flank (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- WDR41 | c.51+920C>T | Intron (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- ZNF684 | c.239-2105T>C | Intron (SNP) | VAF 8/48 reads (17%) | catalogued as rs953990593; called by muse, mutect2, varscan2
